TCGA case TCGA-SI-A71O — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nerve Sheath Tumors; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Washington University St. Louis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a857d684-7195-44f9-ba21-b88020bd9633

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 29 years; Vital status: Dead; Days to death: 694 days (1.9 years).

Diagnoses (3)
1. Malignant peripheral nerve sheath tumor (the primary disease): ICD-O-3 morphology code: 9540/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 29.3 years (10,710 days); Year of diagnosis: 2013; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 12; Tumor length measurement: 14; Tumor width measurement: 12.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 15; Tumor length measurement: 22; Tumor width measurement: 17.
2. Metastasis of diagnosis 1 (Malignant peripheral nerve sheath tumor), site: Lung, NOS. Age at diagnosis: 30.0 years (10,974 days); Days to diagnosis: 264 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.7; Tumor length measurement: 1.3; Tumor width measurement: 0.9.
3. Recurrence of diagnosis 1 (Malignant peripheral nerve sheath tumor), site: Lung, NOS. Age at diagnosis: 31.2 years (11,393 days); Days to diagnosis: 683 days (1.9 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 264 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 264 days.
- Days to follow up: 434 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 545 days (1.5 years); Disease response: With Tumor.
- Day 683 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 683 days (1.9 years).
- Days to follow up: 694 days (1.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 21.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SI-A71O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 500 mg.
  Slide TCGA-SI-A71O-01A-01-TS1: Section location: Top; Percent tumor cells: 96; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SI-A71O-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SI-A71O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 30 mg.
  Slide TCGA-SI-A71O-06A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SI-A71O-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Malignant Peripheral Nerve Sheath Tumors (MPNST); Site of primary tumor other: Right Hip; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: No.
- Primary pathology, Synovial sarcoma: Mpnst nf indicator: No; Mpnst plexiform neurofibroma site: No; Mpnst nf1 genetic testing indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Other (please specify.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 350; Days from index date to pharmaceutical treatment ended: 462; Pharmaceutical therapy drug name: Avastin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Immunotherapy.
- Drug treatment 2: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 350; Days from index date to pharmaceutical treatment ended: 462; Pharmaceutical therapy drug name: Everolimus; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 3: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 489; Pharmaceutical therapy drug name: Tivozanib; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Days from index date to radiation therapy started: 194; Days from index date to radiation therapy ended: 236; Radiation total dose: 6000; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 30; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 694 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 694 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 264 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SI-A71O-01A-12D-A33D-01): tumor purity 0.94, ploidy 1.59, whole-genome doublings 0.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SI-A71O-06A-11D-A386-01): tumor purity 0.46, ploidy 1.73, whole-genome doublings 0.
